Somatic mutation profile of tumor specimen TCGA-19-1791-01A (aliquot TCGA-19-1791-01A-01W-0643-08) from TCGA case TCGA-19-1791, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 82.3 years (30,065 days).
Specimen TCGA-19-1791-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8798bea-3b18-4bf1-9262-7e5c0029660f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-1791-10A (Blood Derived Normal), aliquot TCGA-19-1791-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6d99347-e742-4b55-9ee9-9659e6de4445

The open-access MAF lists 63 somatic variants for this specimen: 43 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 35, Silent 20, Nonsense Mutation 3, Splice Site 2, Nonstop Mutation 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOT9 | c.641C>A p.A214E | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100321394; called by muse, mutect2, varscan2
- ADAMTS16 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775795761, COSV56987268; called by muse, mutect2, varscan2
- AMY2B | c.638C>A p.A213D | Missense Mutation (SNP) | VAF 28/504 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100796448; called by muse, mutect2
- CHD5 | c.3644C>T p.P1215L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.982); catalogued as rs1185828363, COSV99314605; called by muse, mutect2, varscan2
- CNGB1 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV99206951; called by muse, mutect2, varscan2
- CNPY4 | c.114C>G p.C38W | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs143409974; called by muse, mutect2, varscan2
- DDAH1 | c.403+1G>C p.X135_splice | Splice Site (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99395234; called by muse, varscan2
- DND1 | c.994C>T p.L332F | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.259); catalogued as rs1310779709, COSV100298216; called by muse, mutect2
- DOCK7 | c.5505G>A p.W1835* (on ENST00000635253 / NM_001367561.1; = p.W1804* on NM_033407.3) | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | catalogued as COSV99225570; called by muse, mutect2
- EIF3B | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as rs1296455398, COSV62805866; called by muse, mutect2, varscan2
- FO393400.1 | c.418A>C p.K140Q | Missense Mutation (SNP) | VAF 87/191 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99640782; called by muse, mutect2, varscan2
- FOXK2 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs766997277, COSV58877194; called by muse, mutect2
- GABRB3 | c.1109C>T p.T370I | Missense Mutation (SNP) | VAF 44/547 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.285); catalogued as COSV100161249; called by muse, mutect2
- HPS5 | c.851C>A p.A284D (on ENST00000349215 / NM_181507.2; = p.A170D on NM_007216.4) | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.029); catalogued as COSV100834470; called by muse, mutect2
- ICAM1 | c.1432dup p.R478Pfs*3 | Frame Shift Ins (INS) | VAF 7/64 reads (11%) | catalogued as rs1346911918; called by pindel, varscan2
- KCNMB1 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV99211694; called by muse, mutect2, varscan2
- MIIP | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 23/30 reads (77%) | catalogued as COSV99337725; called by muse, mutect2, varscan2
- MPHOSPH10 | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV54905512; called by muse, mutect2
- MRPL15 | c.335C>A p.P112H | Missense Mutation (SNP) | VAF 13/252 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV99477614; called by muse, mutect2
- NHS | c.2285G>A p.G762E | Missense Mutation (SNP) | VAF 92/146 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398124606, COSV66273991; ClinVar: uncertain significance; called by muse, varscan2
- NRG1 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs868075442, COSV99829164; called by muse, mutect2
- NUMBL | c.1466C>A p.P489H | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.43); catalogued as COSV99425053; called by muse, varscan2
- OLFML2B | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 127/150 reads (85%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99668756; called by muse, mutect2, varscan2
- OSBPL10 | c.1830A>C p.K610N | Missense Mutation (SNP) | VAF 68/249 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101159764; called by muse, mutect2, varscan2
- PHF8 | c.3139G>A p.G1047S (on ENST00000357988 / NM_001184896.1; = p.G1011S on NM_015107.3) | Missense Mutation (SNP) | VAF 134/284 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100154676; called by muse, mutect2, varscan2
- PLA2G4D | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.534); catalogued as COSV99299945; called by muse, mutect2, varscan2
- PRAMEF12 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 53/204 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs752655482, COSV100743507; called by muse, mutect2, varscan2
- PTCD1 | c.2102G>C p.*701Sext*35 | Nonstop Mutation (SNP) | VAF 34/136 reads (25%) | catalogued as COSV99464326; called by muse, mutect2, varscan2
- RBMXL2 | c.896C>A p.P299Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.608); catalogued as COSV100182479; called by muse, mutect2, varscan2
- RSPH10B | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 73/332 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV100521379; called by muse, mutect2, varscan2
- SACS | c.3329T>G p.I1110S | Missense Mutation (SNP) | VAF 110/264 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV101207646; called by mutect2, varscan2
- SAMD9 | c.3160T>G p.F1054V | Missense Mutation (SNP) | VAF 69/216 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV101180335; called by muse, mutect2, varscan2
- SP2 | c.1633C>A p.H545N | Missense Mutation (SNP) | VAF 69/121 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV100947274; called by muse, mutect2, varscan2
- SYAP1 | c.532G>C p.D178H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101204965; called by muse, mutect2, varscan2
- TEP1 | c.4558+1G>T p.X1520_splice | Splice Site (SNP) | VAF 140/180 reads (78%) | catalogued as rs1324215129, COSV99403017; called by muse, mutect2, varscan2
- TIMMDC1 | c.571G>T p.G191C | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99956263; called by muse, mutect2
- TINF2 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV99945659; called by muse, mutect2
- TMPRSS9 | c.500C>A p.S167* (on ENST00000648592; = p.S133* on NM_182973.2) | Nonsense Mutation (SNP) | VAF 30/42 reads (71%) | catalogued as COSV100211631; called by muse, varscan2
- XIRP1 | c.4303C>T p.P1435S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.009); catalogued as COSV100453851; called by muse, mutect2, varscan2
- XXYLT1 | c.513C>A p.F171L | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV100118655; called by muse, mutect2
- ZC3H13 | c.2382C>A p.D794E | Missense Mutation (SNP) | VAF 74/1106 reads (7%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs766060723; called by muse, mutect2
- DNAI3 | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- STAG2 | c.1416+1del | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.3687C>T p.S1229= | Silent (SNP) | VAF 93/169 reads (55%) | catalogued as rs555561274, COSV61266250; called by muse, mutect2, varscan2
- AKAP3 | c.351C>T p.N117= | Silent (SNP) | VAF 119/247 reads (48%) | catalogued as rs775062168, COSV57417950; called by muse, mutect2, varscan2
- ATP6V0A4 | c.927G>A p.L309= | Silent (SNP) | VAF 6/144 reads (4%) | catalogued as COSV59480244; called by muse, mutect2
- CD101 | c.1236T>C p.S412= | Silent (SNP) | VAF 60/140 reads (43%) | catalogued as COSV99870074; called by muse, mutect2, varscan2
- DMBX1 | c.24C>A p.G8= | Silent (SNP) | VAF 14/282 reads (5%) | catalogued as COSV100760862; called by muse, mutect2
- FGD1 | c.969C>T p.A323= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100911226; called by muse, mutect2, varscan2
- FLG | c.4704C>T p.A1568= | Silent (SNP) | VAF 50/186 reads (27%) | catalogued as rs766533034, COSV100910376, COSV64238428; called by muse, mutect2, varscan2
- GAL3ST2 | c.243C>T p.S81= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs765418616, COSV99510872, COSV99511106; called by muse, mutect2, varscan2
- GPRC5C | c.1449C>T p.Y483= (on ENST00000652232; = p.Y438= on NM_018653.4) | Silent (SNP) | VAF 20/162 reads (12%) | catalogued as rs771601951, COSV100702977; called by muse, mutect2, varscan2
- GRPR | c.399G>A p.A133= | Silent (SNP) | VAF 93/197 reads (47%) | catalogued as rs1299617422, COSV66669612; called by muse, mutect2, varscan2
- HTR3B | c.411G>T p.V137= | Silent (SNP) | VAF 27/440 reads (6%) | catalogued as COSV99492199; called by muse, mutect2
- IGSF22 | c.1917G>A p.V639= | Silent (SNP) | VAF 83/197 reads (42%) | catalogued as COSV100080216; called by muse, mutect2, varscan2
- MOCOS | c.1419G>A p.S473= | Silent (SNP) | VAF 77/141 reads (55%) | catalogued as rs756236625, COSV99733784; called by muse, mutect2, varscan2
- NFAM1 | c.576G>A p.R192= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs745505910, COSV100216035; called by muse, mutect2, varscan2
- OR2D2 | c.678C>A p.V226= | Silent (SNP) | VAF 79/296 reads (27%) | catalogued as COSV100203902; called by muse, mutect2, varscan2
- PCDHA9 | c.1389C>T p.F463= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV65330020; called by muse, mutect2, varscan2
- PTPRT | c.729C>G p.V243= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV61980570; called by muse, mutect2
- TMPRSS7 | c.1560C>T p.S520= (on ENST00000452346; = p.S394= on NM_001042575.2) | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV101340153; called by muse, mutect2
- ZFYVE9 | c.1416T>C p.N472= | Silent (SNP) | VAF 94/181 reads (52%) | catalogued as COSV99820544; called by muse, mutect2, varscan2
- ZNF280B | c.1272G>C p.T424= | Silent (SNP) | VAF 102/135 reads (76%) | catalogued as rs192821344, COSV100840413; called by muse, varscan2
